Gene-level copy-number profile of tumor specimen TCGA-HU-A4H6-01A from TCGA case TCGA-HU-A4H6, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 72.4 years (26,445 days).
Specimen TCGA-HU-A4H6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.d20866cf-31e7-4018-a094-c830f7421181.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HU-A4H6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6ddf9846-ad65-43c2-96ea-1af06dce4c9c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 6,568; copy number 2: 40,944; copy number 3: 10,580; copy number 4: 959; copy number 5: 498; copy number 6: 40; copy number 7: 174; copy number 11: 9; copy number 13: 10; copy number 14: 26; copy number 38: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HU-A4H6-01A-11D-A253-01): tumor purity 0.23, ploidy 2.61, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:1,623,806–2,245,605, 1 gene (within-gene range 0–3): GMDS.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 766 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:147,732,063–148,072,776, 1 gene, copy number 5 (within-gene range 2–5): ARHGAP10.
- chr4:147,808,926–151,015,727, 30 genes, copy number 5 (within-gene range 1–5): RN7SL254P, AC115621.1, NR3C2, AC069272.1, AC002460.2, ASS1P8, RNA5SP166, AC108935.1, ATP5MGP4, AC093648.1, AC002460.1, RNU7-197P, AC108156.1, LINC02430, LINC02355, IQCM, AC108168.1, AC093893.1, AKIRIN2P1, RNA5SP167, RNU6-1230P, AC105343.1, AC105343.2, DCLK2, RNU7-194P, LRBA, AC092612.1, AC110813.1, MAB21L2, ZBTB8OSP1.
- chr9:33,706,679–36,304,781, 135 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr9:89,639,814–90,082,569, 7 genes, copy number 6 (within-gene range 2–6): UNQ6494, BX470209.2, BX470209.1, AL161629.1, MIR4290HG, MIR4290, IL6RP1.
- chr10:120,608,580–121,615,839, 12 genes, copy number 14–38 (within-gene range 3–38): AC023282.1, WDR11-AS1, AL391425.1, WDR11, AC010998.2, AC010998.1, AC010998.3, RPL19P16, LINC01153, RN7SKP167, FGFR2, AC009988.1.
- chr10:127,549,309–128,085,855, 9 genes, copy number 11 (within-gene range 2–11): NPS, AL391005.1, FOXI2, BUB1P1, CLRN3, PTPRE, AL158166.2, AL158166.1, AL390236.1.
- chr11:66,435,075–83,193,794, 484 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr11:83,209,399–83,213,404, 3 genes, copy number 6: CKS1BP4, AP000873.3, AP000873.1.
- chr11:124,302,831–125,164,609, 49 genes, copy number 5 (within-gene range 2–5): OR8D1, OR8D2, OR8B7P, OR8B6P, OR8B5P, OR8B1P, OR8C1P, OR8B2, OR8B3, OR8X1P, AP001804.1, OR8B4, OR8B8, OR8A2P, OR8B9P, OR8B10P, OR8A3P, AP000916.1, OR8B12, OR8A1, OR8Q1P, PANX3, TBRG1, SIAE, RNA5SP352, SPA17, NRGN, AP000866.5, VSIG2, ESAM, AP000866.2, MSANTD2, AP000866.6, AP000866.3, AP000866.1, AP000866.4, ROBO3, AP003501.1, ROBO4, AP003501.2, HEPACAM, HEPN1, CCDC15-DT, CCDC15, SLC37A2, TMEM218, KRT18P59, AP001007.2, PKNOX2-AS1.
- chr11:125,188,115–125,277,657, 3 genes, copy number 5: AP001007.3, AP001007.1, RNU6-321P.
- chr19:47,713,422–47,768,840, 4 genes, copy number 14: EHD2, NOP53, SNORD23, NOP53-AS1.
- chr19:50,797,704–50,896,398, 10 genes, copy number 13: C19orf48, SNORD88C, AC010325.3, LINC01869, KLK1, KLK15, AC011523.1, KLK3, KLK2, KLKP1.
- chr19:51,689,128–51,986,856, 19 genes, copy number 14: SPACA6, MIR99B, MIRLET7E, MIR125A, HAS1, FPR1, FPR2, AC018755.5, FPR3, ZNF577, AC006272.1, AC006272.2, AC074141.1, ZNF649-AS1, ZNF649, AC011460.1, ZNF613, ZNF350-AS1, ZNF350.

Autosomal genes at a single copy (total copy number 1): 6,005. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
